Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAHN, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAHN-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 3.0 cm; no angio-invasion present; no invasion in rete testis; lymphatic invasion present; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD O-3
Seminoma NOS 9061/3
Site: @ Testis NOS C62.9
HJ 37/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 461ed80d-9112-4f28-b89d-97f89abf9e5b (TCGA-2G-AAHN.C5A90468-70E4-4A77-A957-EF0E1020976F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).